FM case AD15544 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/2a9a093f-0a71-4644-b43b-65d6248ee768

Female, 53.7 years: Carcinoma, NOS (ICD-O-3 8010/3) of the kidney; metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 63% (pathologist estimate recorded by GDC). Sample type: Metastatic.
